Gene-level copy-number profile of tumor specimen TCGA-13-1495-01A from TCGA case TCGA-13-1495, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 60.4 years (22,046 days).
Specimen TCGA-13-1495-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.c7844e0a-4d80-4c61-902d-5600c23eebd1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1495-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eedc6aca-d1d0-4a42-ab09-4a5910211354

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 182; copy number 2: 11,554; copy number 3: 13,745; copy number 4: 21,385; copy number 5: 5,269; copy number 6: 4,213; copy number 7: 1,715; copy number 8: 665; copy number 9: 476; copy number 10: 244; copy number 11: 207; copy number 12: 3; copy number 13: 132; copy number 15: 3; copy number 17: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1495-01A-01D-0472-01): tumor purity 0.82, ploidy 3.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,021 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,681,570–38,214,806, 29 genes, copy number 13: C1orf109, CDCA8, EPHA10, Y_RNA, ACTN4P2, AL929472.1, MANEAL, AL929472.3, YRDC, C1orf122, MTF1, AL929472.4, AL929472.2, INPP5B, SNORA63, RNU6-584P, Metazoa_SRP, SF3A3, RNU6-510P, FHL3, UTP11, POU3F1, MIR3659HG, AL139158.1, MIR3659, LINC02786, AL390839.1, AL390839.2, LINC01343.
- chr1:61,742,477–62,178,675, 1 gene, copy number 10 (within-gene range 4–10): PATJ.
- chr1:62,038,842–65,415,871, 78 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).
- chr1:180,230,264–180,976,482, 14 genes, copy number 13: LHX4, ACBD6, VDAC1P4, MIR3121, OVAAL, Y_RNA, XPR1, U6, LINC02816, KIAA1614, AL162431.1, KIAA1614-AS1, AL162431.2, AL162431.3.
- chr1:200,551,497–201,584,367, 29 genes, copy number 10 (within-gene range 6–10): KIF14, DDX59, DDX59-AS1, CAMSAP2, RPL34P6, GPR25, INAVA, MROH3P, RNU6-704P, KIF21B, AL358473.1, AL358473.2, CACNA1S, ASCL5, TMEM9, IGFN1, AC103925.1, PKP1, TNNT2, AC119427.2, LAD1, AC119427.1, TNNI1, AC096677.3, PHLDA3, AC096677.2, CSRP1, AC096677.1, RPS10P7.
- chr2:3,481,242–4,945,383, 23 genes, copy number 9: TRAPPC12-AS1, AC114810.1, ADI1, AC231981.1, AC108488.1, AC108488.2, RNASEH1, RNASEH1-AS1, AC108488.3, RPS7, COLEC11, AC010907.2, TMSB4XP2, ALLC, GAPDHP48, AC010907.1, DCDC2C, LINC01304, AC012445.1, NPM1P48, LINC01249, AC092169.1, RNU6-649P.
- chr2:185,425,063–185,547,818, 2 genes, copy number 9: AC009315.1, ELF2P4.
- chr3:109,241,507–112,294,227, 40 genes, copy number 10: AC063923.1, DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12, LINC01205, PPIAP15, MIR4445, AC078980.1, DIMT1P1, NFYBP1, AC078918.1, AC117430.1, RNU6ATAC15P, RPSAP29, Y_RNA, NECTIN3-AS1, NECTIN3, CD96, AC092916.1, ATP6V0CP2, AC092916.2, ZBED2, NT5C3AP2, PLCXD2, PLCXD2-AS1, PHLDB2, AC117509.1, ABHD10, TAGLN3, RFKP2, TMPRSS7, C3orf52, MIR567, GCSAM, TBILA, SLC9C1, AC128688.1.
- chr3:131,361,898–135,439,888, 65 genes, copy number 10–13 (broad region; genes not listed).
- chr3:138,160,988–141,807,919, 70 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr3:145,684,572–147,370,656, 20 genes, copy number 9 (within-gene range 6–9): GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1, AC092957.1, LINC02010, RNU6-505P.
- chr3:148,279,682–151,499,806, 84 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr3:169,613,510–174,378,005, 86 genes, copy number 11–15 (broad region; genes not listed).
- chr3:174,631,823–174,632,064, 1 gene, copy number 12: RN7SKP40.
- chr3:187,932,764–193,176,864, 53 genes, copy number 11–17: AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC, OSTN, OSTN-AS1, UTS2B, CCDC50, AC073365.1, PYDC2, Y_RNA, AC026320.2, AC026320.1, AC026320.3, RN7SKP222, FGF12, FGF12-AS1, FGF12-AS2, FGF12-AS3, AC026671.1, RNU1-20P, MB21D2, AC092966.1, VEZF1P1.
- chr3:194,533,503–197,573,323, 112 genes, copy number 9 (broad region; genes not listed).
- chr3:197,580,344–197,580,629, 1 gene, copy number 9: AC132008.1.
- chr5:36,098,407–41,261,438, 87 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr9:12,685,439–15,307,360, 39 genes, copy number 10: TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B.
- chr9:16,726,814–17,114,122, 7 genes, copy number 10: BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1.
- chr9:78,219,120–79,198,314, 7 genes, copy number 10: AL353705.3, CEP78, PSAT1, AL592221.1, MTND2P8, KRT18P24, AL512634.1.
- chr12:17,083,531–20,753,386, 41 genes, copy number 9 (within-gene range 6–9): AC092110.1, RPL7P40, PSMC1P8, TIMM17BP1, AC048352.1, LINC02378, MIR3974, Y_RNA, RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1.
- chr12:22,573,425–26,299,290, 54 genes, copy number 9 (within-gene range 7–9): LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1, SOX5, AC087260.1, MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5.
- chr12:31,280,584–34,249,958, 78 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 182. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
